Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GL, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GL-06A (Metastatic).

[page 1 of 2]
ICD-0-3

Melanoma, malignant NOS
8720/3
Site: Axillary lymph node
C77.3
JAD 11/4/13

DIAGNOSIS

(A) LEFT ARM, SKIN ELLIPSE:

Skin and soft tissue resection with healing surgical scar. See note.

Note: There is no malignant melanoma identified in these sections. Margins have been evaluated.

(B) LEFT AXILLARY CONTENTS:

METASTATIC MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE, 38 X 35 MM, EXCISION.

METASTATIC MALIGNANT MELANOMA PRESENT IN ONE OF THIRTY-EIGHT LYMPH NODES (1/38).

METASTATIC MELANOMA IS CAPSULAR AND MEASURES 0.6 X 0.2 MM.

No extracapsular extension

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) WIDE RE-EXCISION, LEFT ARM MELANOMA - A tan hair-bearing skin ellipse (8.2 x 2.5 x 1.4 cm) tagged long anterior and short distal (tip at 6 o'clock). A well-healed, 3.8 cm, linear scar runs to the 6 o'clock tip. A slight 0.1 cm tan nodule is located in the center of the specimen, 1.0 cm from the posterior (9 o'clock) margin and 1.4 cm from the anterior (3 o'clock) margin.

INK CODE: Blue - 12 to 6 o'clock. Orange - 6 to 12 o'clock.

SECTION CODE: A1, 12 o'clock, proximal tip; A2, 6 o'clock, distal tip; A3, 12 to 3 o'clock margin, en face; A4, 3 to 6 o'clock margin, en face; A5, 6 to 9 o'clock margin, en face; A6, 9 to 12 o'clock margin, en face; A7, deep margin, en face; A8-A10, section through skin with scar.

(B) LEFT AXILLARY CONTENTS - A portion of lobulated fibroadipose tissue (17.0 x 14.0 x 4.5 cm) with overlying tan skin ellipse (13.5 x 1.8 cm) with a linear scar (3.5 cm). A palpable mass (3.8 x 3.5 x 3.5 cm) appears adherent to the underlying portion of the skin. The tumor comes to within 0.2 cm of the superficial margin adjacent to the skin. The tumor is heterogeneous and well-circumscribed with focal areas of possible infiltration into adjacent adipose tissue. The remainder of the fibroadipose tissue contains forty-two possible lymph nodes ranging in size from 0.2 x 0.2 x 0.2 cm to 2.5 x 2.0 x 1.0 cm. The lymph nodes range from pink-white to tan-gray with prominent fatty replacement.

INK CODE: Orange - superficial fibrous tissue over tumor and adjacent to skin. Blue - side adjacent to tumor.

SECTION CODE: B1, B2, skin with adjacent tumor; B3, B4, tumor adjacent to superficial fibrous tissue; B5-B7, representative sections of tumor; B8, B9, one node serially sectioned; B10, B11, one node serially sectioned; B12, one node serially sectioned; B13, one whole node; B14, one bisected node; B15, one bisected node; B16, one bisected node; B17, two nodes; B18, three nodes; B19, three nodes; B20, three nodes; B21, three nodes; B22, four nodes; B23, one node trisected; B24, five possible nodes; B25, five possible nodes; B26, five possible nodes; B27, six possible nodes.

CLINICAL HISTORY

Melanoma

SNOMED CODES

T-02610, M-78060, T-C4710, M-87206, T-D100, M-87206

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

IF REPORT-----

[page 2 of 2]
IHP-5A Discrepancy		☒

Source: NCI Genomic Data Commons file 36ac15e9-8d1c-4e0b-bd62-402145c586d8 (TCGA-D3-A5GL.AEA99FF4-044A-45F7-B2F2-9F17F675FA79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).